Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PS-05A (Additional - New Primary).

[page 1 of 2]
2nd of two Primaries
(sent at same time)

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Female
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Right kidney, partial nephrectomy:

1. Renal cell carcinoma, papillary (chromophil) type, Fuhrman nuclear grade 3, 3.6 cm in greatest dimension.
2. Tumor extends into but not through the overlying renal capsule.
3. Tumor approaches focally to within 0.1 cm of parenchymal resection margin, but is not seen at the margin itself.
4. Incidental benign simple renal cyst, 0.6 cm.

COMMENT:

Kidney Tumor Synoptic Comment:

- Histologic type: Papillary (chromophil) type.
- Grade: Fuhrman nuclear grade 3 (of 4)
- Maximum tumor diameter: 3.6 cm.
- Renal pelvis: Not present.
- Ureter: Not present.
- Renal sinus: Not present.
- Hilar renal veins: Not present.
- Intrarenal veins and lymphatics: Normal.
- Adrenal gland: Not identified.
- Capsule/perirenal fat: Tumor invades but does not extend through capsule.
- Hilar lymph nodes (number positive/number of nodes): Not applicable.
- Resection margins: Negative.
- Proximity to nearest margin: 0.1 from parenchymal resection margin.
- Stage: pT1aNXMX.
- Additional Comments: Select slides (slides A1 and A4) were shown at the departmental , and the faculty in attendance concurred with the above diagnoses on [REDACTED]

ICD O-3
Carcinoma, papillary renal
cell (chromophil) 8260/3
Site R Kidney NOS C64.9
W 8/30/14

Specimen(s) Received

[page 2 of 2]
A:Right Partial Nephrectomy

Clinical History

The patient is a [redacted] year-old woman with history of papillary renal cell carcinoma in the left kidney. She now has a mass in the right kidney and undergoes partial nephrectomy.

Gross Description

The specimen is received fresh in one part, labeled with the patient's name and medical record number and "Right kidney mass." It consists of a red-brown, firm partial nephrectomy specimen, measuring 21 x 5 x 4 cm and weighing 28.3 gm. There is a white-yellow, solid, firm, spheroid, lobulated, and encapsulated mass, measuring 3.6 cm in diameter, replacing >95% of the kidney parenchyma. This mass abuts the parenchymal resection margin in multiple areas. In addition, there is a white-yellow, uninoculated cyst, measuring 0.6 cm in diameter, located on the kidney surface. This cyst is 3.2 cm from the resection margin. The resection margin is inked black for microscopic evaluation. The specimen was opened to show the surgeon the tumor in relation to the resection margin.

Representative sections are submitted as follows:

Cassette A1: Tumor in closest approach to resection margin.
Cassette A2: Representative section of tumor and cyst.
Cassette A3: Representative section of tumor and renal parenchyma.
Cassettes A4-A5: Representative sections of tumor.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[redacted] Pathology Resident

Electronically signed out on [redacted] Pathologist

2nd of 2 primaries - sent at same time.

Source: NCI Genomic Data Commons file d3f7ef8c-3684-487b-850a-b1afdd1e2b3e (TCGA-UZ-A9PS.BAE8C63F-81B6-431A-9431-23ACAC11BAD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).